Surgical pathology report (de-identified scan), TCGA case TCGA-ED-A5KG, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Asterand, specimen TCGA-ED-A5KG-01A (Primary Tumor).

Gross Description: Tumor is moderate-margins with 5x4x4cm in size, yellow-white, soft in cutting section.

Microscopic Description: Tumor cells form the trabecular patterns, or acinar or sheets or tubular patterns intervening in benign hepatic tissue. The tumor cells retain apolygonal shape and have very irregular round vesicular nuclei with prominent nucleoli. The amount of cytoplasm are abundant and the cytoplasm is basenophilic or clear. Nuclei are irregularly large and hyperchromatic with prominent nucleoli. Mitoses are present. Tumor is necrotic and hemorrhage.

Diagnosis Details: Hepatocellular carcinoma, moderately-differentiated

Comments:

Formatted Path Reports: LIVER TISSUE CHECKLIST

Specimen type: Lobectomy

Tumor size: 5 x 4 x 4 cm

Focality: Not specified

Histologic type: Hepatocellular carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Not specified

Lymph nodes: Not specified

Venous invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-O-3

Carcinoma, hepatocellular

Site: Liver, Hepatic NOS

817013
C22.0
MD 2/1/13

Source: NCI Genomic Data Commons file 1066b51f-ff33-4968-b64d-3c29a106a95f (TCGA-ED-A5KG.87394A2B-7AF7-49E0-9ED0-6FFCC899EC38.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).